Somatic mutation profile of tumor specimen TCGA-DD-AAVY-01A (aliquot TCGA-DD-AAVY-01A-11D-A40R-10) from TCGA case TCGA-DD-AAVY, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 56.7 years (20,709 days).
Specimen TCGA-DD-AAVY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63425b14-eba7-42d4-a602-9b6a978bf552.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAVY-10A (Blood Derived Normal), aliquot TCGA-DD-AAVY-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d27f409b-7059-4f15-bc56-e92d785700cd

The open-access MAF lists 104 somatic variants for this specimen: 81 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 21, Nonsense Mutation 6, Frame Shift Del 3, Splice Site 3, Splice Region 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 51/121 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.241G>C p.G81R | Missense Mutation (SNP) | VAF 27/49 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960075, COSV67960449, COSV67960680; called by muse, mutect2, varscan2
- ABCG4 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV56646386; called by muse, mutect2, varscan2
- ACAT2 | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 49/55 reads (89%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs764262503, COSV100887182; called by muse, mutect2, varscan2
- AFDN | c.2719G>T p.E907* | Nonsense Mutation (SNP) | VAF 40/44 reads (91%) | catalogued as COSV100653347; called by muse, mutect2, varscan2
- ANKFY1 | c.2648A>G p.D883G (on ENST00000341657 / NM_001330063.2; = p.D884G on NM_016376.5) | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100493035; called by muse, mutect2, varscan2
- ARMCX3 | c.476T>A p.I159N | Missense Mutation (SNP) | VAF 86/183 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100362315; called by muse, mutect2, varscan2
- ATP2B4 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs765757084, COSV100397940; called by muse, mutect2, varscan2
- CAND1 | c.3460A>G p.T1154A | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV101607347; called by muse, mutect2, varscan2
- CAVIN1 | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 44/104 reads (42%) | catalogued as COSV100824589; called by muse, mutect2, varscan2
- CC2D2B | c.156G>C p.Q52H | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100729527, COSV60358553; called by muse, mutect2, varscan2
- CDH18 | c.2206C>A p.Q736K | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs762348492, COSV56922945, COSV99937365; called by muse, mutect2, varscan2
- CDH9 | c.2267T>A p.L756H | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.84); catalogued as COSV99151115; called by muse, mutect2, varscan2
- COL16A1 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1175110562, COSV99595165; called by muse, mutect2, varscan2
- COL20A1 | c.2629C>T p.L877F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100491139; called by muse, mutect2, varscan2
- COPG1 | c.1663A>T p.I555F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV100135839; called by muse, mutect2, varscan2
- CYP2F1 | c.1210A>G p.T404A | Missense Mutation (SNP) | VAF 78/324 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100462896; called by muse, mutect2, varscan2
- DNAH8 | c.1817T>C p.L606S | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.292); catalogued as COSV100546687; called by muse, mutect2, varscan2
- EXPH5 | c.811A>G p.I271V | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as rs1235597923, COSV99762020; called by muse, mutect2, varscan2
- FAM167A | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as rs376899787; called by muse, mutect2, varscan2
- FAM171A1 | c.2556G>T p.Q852H | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100968429; called by muse, mutect2, varscan2
- FLRT2 | c.1538C>A p.T513N | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV100420814; called by muse, mutect2, varscan2
- GCC1 | c.1571T>G p.L524R | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100365613; called by muse, mutect2, varscan2
- GEMIN6 | c.46A>G p.I16V | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1558337463, COSV99931645; called by muse, mutect2, varscan2
- GK2 | c.404A>T p.N135I | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV100726016; called by muse, mutect2, varscan2
- GPR101 | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 114/118 reads (97%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99981563; called by muse, mutect2, varscan2
- GPR37L1 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.291); catalogued as COSV66162522, COSV66162673; called by muse, mutect2, varscan2
- GRM1 | c.870C>A p.F290L | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99268244; called by muse, mutect2, varscan2
- HCAR2 | c.934T>C p.C312R | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1236755442, COSV100186596; called by muse, mutect2, varscan2
- HCAR3 | c.934T>C p.C312R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100811714; called by muse, mutect2, varscan2
- HELB | c.3181G>C p.V1061L | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.197); catalogued as COSV99922123; called by muse, mutect2, varscan2
- HERC2 | c.8121-2A>T p.X2707_splice | Splice Site (SNP) | VAF 108/261 reads (41%) | catalogued as COSV99875926; called by muse, mutect2, varscan2
- HHIP | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99667667; called by muse, mutect2, varscan2
- HORMAD1 | c.873A>G p.E291= | Splice Region (SNP) | VAF 68/238 reads (29%) | catalogued as COSV100464352; called by mutect2, varscan2
- KLHL42 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs911425310, COSV101179838; called by muse, mutect2, varscan2
- KRT38 | c.1276T>A p.C426S | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99878326; called by muse, mutect2, varscan2
- LPAR1 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs769282124, COSV100730979; called by muse, mutect2, varscan2
- LTBP2 | c.2692G>T p.G898* | Nonsense Mutation (SNP) | VAF 15/87 reads (17%) | catalogued as rs1208099717, COSV100000800, COSV56214876; called by muse, mutect2, varscan2
- MANEA | c.332A>G p.Y111C | Missense Mutation (SNP) | VAF 55/64 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1353903169, COSV62589365; called by muse, mutect2, varscan2
- MAP3K15 | c.2051C>G p.P684R | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as COSV100135390, COSV58825490; called by muse, mutect2, varscan2
- MCM2 | c.1937A>G p.N646S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99413376; called by muse, mutect2, varscan2
- ME3 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs1359610201, COSV60165513; called by muse, mutect2
- MED13L | c.2264A>G p.D755G | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV99929765; called by muse, mutect2, varscan2
- MEGF8 | c.7922A>G p.Q2641R (on ENST00000251268 / NM_001271938.2; = p.Q2574R on NM_001410.3) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99238365; called by muse, mutect2, varscan2
- MIB2 | c.1066G>C p.G356R | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100599006; called by muse, mutect2, varscan2
- MRPL14 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 33/179 reads (18%) | catalogued as rs770659477, COSV100921050; called by muse, mutect2, varscan2
- MUC16 | c.31223G>A p.G10408E | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.237); catalogued as rs1469725692, COSV67467755; called by muse, mutect2, varscan2
- NMRK1 | c.536T>C p.L179S | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100738050; called by muse, mutect2, varscan2
- NOC4L | c.907del p.X303_splice | Splice Site (DEL) | VAF 3/29 reads (10%) | catalogued as rs765400964; called by pindel, varscan2
- NUP153 | c.3431A>G p.E1144G | Missense Mutation (SNP) | VAF 86/120 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.181); catalogued as COSV100020696; called by muse, mutect2, varscan2
- OR5M3 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 79/181 reads (44%) | catalogued as rs138643585, COSV100392638, COSV56568478; called by muse, mutect2, varscan2
- PCYT2 | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.696); catalogued as COSV100326023; called by muse, mutect2, varscan2
- PLA2G15 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV99547332; called by muse, mutect2, varscan2
- PLP1 | c.250del p.A84Pfs*30 | Frame Shift Del (DEL) | VAF 101/255 reads (40%) | catalogued as CM102499; called by mutect2, pindel, varscan2
- PTK2B | c.2942A>G p.H981R | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99532436; called by muse, mutect2, varscan2
- RBM27 | c.637A>G p.S213G | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99506480; called by muse, mutect2, varscan2
- RELN | c.4474G>A p.E1492K | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV100634497; called by muse, mutect2, varscan2
- REM1 | c.29A>G p.K10R | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV52429140; called by muse, mutect2, varscan2
- RINT1 | c.455T>A p.I152N | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV57557855, COSV99994531; called by muse, mutect2
- RIPOR1 | c.3145G>C p.V1049L (on ENST00000379312 / NM_001193522.2; = p.V1045L on NM_024519.4) | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.91); PolyPhen benign (0.044); catalogued as COSV99243470; called by muse, mutect2, varscan2
- SLC35F5 | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as rs776435612, COSV55519170, COSV99830170; called by muse, mutect2, varscan2
- SLC39A10 | c.1496T>G p.L499R | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62768316; called by muse, mutect2, varscan2
- SLC41A1 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.209); catalogued as COSV100900457; called by muse, mutect2, varscan2
- SRCAP | c.6350C>T p.S2117L | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV99351005; called by muse, varscan2
- TMEM140 | c.119C>G p.T40S | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV99313286; called by muse, mutect2, varscan2
- TMEM8B | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100941693; called by muse, mutect2, varscan2
- UBR5 | c.6014A>T p.N2005I | Missense Mutation (SNP) | VAF 77/346 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.059); catalogued as COSV99641907; called by muse, mutect2, varscan2
- USH2A | c.11558G>T p.G3853V | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100239922, COSV56349823, COSV56458370; called by muse, mutect2, varscan2
- WBP11 | c.404A>T p.E135V | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99660821; called by muse, mutect2, varscan2
- XBP1 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 50/72 reads (69%) | catalogued as COSV53275854, COSV99321748; called by muse, mutect2, varscan2
- ZNF296 | c.861G>T p.Q287H | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); catalogued as COSV99674056; called by muse, mutect2, varscan2
- ZNF471 | c.86A>C p.Q29P | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV100340771; called by muse, mutect2, varscan2
- ZNF518A | c.3146G>A p.G1049D | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV100283643; called by muse, mutect2, varscan2
- ZNF750 | c.1098C>A p.N366K | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as COSV99489899; called by muse, mutect2, varscan2
- ABCA12 | c.1953del p.Y651* (on ENST00000272895 / NM_173076.3; = p.Y333* on NM_015657.3) | Frame Shift Del (DEL) | VAF 47/121 reads (39%) | called by mutect2, pindel, varscan2
- DLEC1 | c.1572+2_1572+3del p.X524_splice | Splice Site (DEL) | VAF 34/90 reads (38%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.1961A>G p.N654S | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HBG2 | c.173A>T p.N58I | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LYZL6 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRR12 | c.29G>C p.G10A (on ENST00000615927; = p.R405S on NM_020719.3) | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT tolerated, low confidence (0.8); PolyPhen possibly damaging (0.551); called by mutect2, varscan2
- RPLP0 | c.815_818del p.P272Lfs*63 | Frame Shift Del (DEL) | VAF 81/210 reads (39%) | called by mutect2, pindel, varscan2
- BCHE | c.780G>A p.A260= | Silent (SNP) | VAF 74/176 reads (42%) | catalogued as rs773199170, COSV100012896, COSV52253236; called by muse, mutect2, varscan2
- CDH9 | c.2268C>A p.L756= | Silent (SNP) | VAF 55/140 reads (39%) | catalogued as COSV99151110; called by muse, mutect2, varscan2
- COLGALT1 | c.1530G>T p.L510= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as COSV99395216; called by muse, mutect2, varscan2
- CPS1 | c.1629T>C p.A543= | Silent (SNP) | VAF 61/120 reads (51%) | catalogued as COSV99243769; called by muse, mutect2, varscan2
- FAT3 | c.7149C>T p.Y2383= | Silent (SNP) | VAF 48/76 reads (63%) | catalogued as rs770367803, COSV99969037; called by muse, mutect2, varscan2
- FIP1L1 | c.381A>G p.R127= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as rs755184908, COSV100184618; called by muse, mutect2, varscan2
- HSPA2 | c.867G>A p.S289= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV55968536, COSV99905090; called by muse, mutect2, varscan2
- ITGAE | c.498T>C p.G166= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV99561380; called by muse, mutect2, varscan2
- ITGAM | c.3054C>G p.A1018= (on ENST00000648685 / NM_001145808.2; = p.A1017= on NM_000632.4) | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV99792922; called by muse, mutect2, varscan2
- KCNC1 | c.537C>A p.L179= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV99789593; called by muse, mutect2
- KLK13 | c.117C>T p.G39= | Silent (SNP) | VAF 8/129 reads (6%) | catalogued as COSV99335416; called by muse, mutect2
- KRT20 | c.909T>C p.H303= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs1453358125, COSV99391538; called by muse, mutect2, varscan2
- MRPL15 | c.447G>A p.T149= | Silent (SNP) | VAF 30/371 reads (8%) | catalogued as rs1456973462, COSV99477584; called by muse, mutect2
- MS4A14 | c.1917G>T p.L639= | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as COSV100280654; called by muse, mutect2, varscan2
- PCYT2 | c.1104G>C p.L368= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV100326026; called by muse, mutect2, varscan2
- SLC6A19 | c.1650C>T p.F550= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs763114840, COSV57253628; called by muse, mutect2, varscan2
- THSD7A | c.4812A>G p.L1604= | Silent (SNP) | VAF 38/58 reads (66%) | catalogued as rs1283722519, COSV101349195; called by muse, mutect2, varscan2
- TMC1 | c.1455T>C p.N485= | Silent (SNP) | VAF 54/133 reads (41%) | catalogued as rs1564557522, COSV99920199; called by muse, mutect2, varscan2
- WDFY3 | c.6120A>G p.V2040= | Silent (SNP) | VAF 91/212 reads (43%) | catalogued as COSV99884987; called by muse, mutect2, varscan2
- ZBTB7B | c.357A>G p.P119= (on ENST00000292176; = p.P153= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV99421443; called by muse, mutect2, varscan2
- ZNF606 | c.2091A>G p.A697= | Silent (SNP) | VAF 50/107 reads (47%) | catalogued as COSV100071944; called by muse, mutect2, varscan2
- MIR409 | n.57C>A | RNA (SNP) | VAF 56/106 reads (53%) | called by muse, mutect2, varscan2
- SCRIB | c.642+10G>T | Intron (SNP) | VAF 164/223 reads (74%) | catalogued as COSV100253911; called by muse, mutect2, varscan2
